MMRF case MMRF_1782 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6e77b994-947e-48b6-9db7-0be77be48faa

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.0 years (23,374 days); ISS stage: I; Days to last known disease status: 1,009 days (2.8 years); Days to last follow up: 1,009 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 574 days (1.6 years); Days to treatment end: 727 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 727 days (2.0 years); Days to treatment end: 835 days (2.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -26 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 57.7 mg/dL; Immunoglobulin G 5.06 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.71 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 6.83 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 4.84 mmol/L; C-Reactive Protein 0.5 mg/dL.
- Day 113 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.25 mg/dL; Immunoglobulin G 4.12 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 6.28 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 7.92 mmol/L.
- Day 176 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 0.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 3.09 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 16.6 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 23.3 ×10⁹/L; Absolute Neutrophil 17 ×10⁹/L; Platelets 82 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.23 mmol/L.
- Day 272 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 4.97 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.73 g/L; Lactate Dehydrogenase 6.55 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 4.9 mmol/L.
- Day 414 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 5.75 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.73 g/L; Lactate Dehydrogenase 6.07 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 5.72 mmol/L.
- Day 562: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.1 mg/dL; Immunoglobulin G 5.73 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.76 g/L; Beta 2 Microglobulin 0.81 µg/mL; Lactate Dehydrogenase 6.3 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.39 mmol/L.
- Day 639 (ECOG 0): Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 7.38 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 8.09 mmol/L.
- Day 744: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Immunoglobulin G 3.54 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 7.38 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.28 mmol/L.
- Day 806 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 4.24 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 7.88 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.94 mmol/L.
- Day 919 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.61 mg/dL; Immunoglobulin G 3.79 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 7.72 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.78 mmol/L.
- Day 1,009 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 31.8 mg/dL; Immunoglobulin G 3.75 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 0.77 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 7.21 mmol/L.

Other clinical attributes
- Day -26: Weight: 79 kg; Height: 161 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1782_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -26 days.
- Sample MMRF_1782_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -26 days.
